TCGA case TCGA-LI-A67I — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Hartford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4482da24-bd16-4826-a9ea-1078bcb12411

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Alive.

Diagnoses (2)
1. Malignant fibrous histiocytoma (the primary disease): ICD-O-3 morphology code: 8830/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 75.8 years (27,671 days); Year of diagnosis: 2013; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 14; Tumor length measurement: 25; Tumor width measurement: 15.2.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 15; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Tumor burden: 25.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 20; Tumor width measurement: 15.
   Pathology details: Measurement type: Pathologic; Tumor burden: 20.
2. Metastasis of diagnosis 1 (Malignant fibrous histiocytoma), site: Lung, NOS. Age at diagnosis: 77.3 years (28,245 days); Days to diagnosis: 574 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (5 entries)
- Days to follow up: 160 days; Disease response: Tumor Free.
- Days to follow up: 433 days (1.2 years); Disease response: Tumor Free.
- Day 574 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 574 days (1.6 years).
- Days to follow up: 670 days (1.8 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 922.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 10.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LI-A67I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 1,610 mg.
  Slide TCGA-LI-A67I-01A-03-TSC: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-LI-A67I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LI-A67I-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic length: 25.0; Lesion radiologic depth: 14.0.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 595; Pharmaceutical therapy drug name: Doxil; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Radiation treatment: Days from index date to radiation therapy started: 67; Days from index date to radiation therapy ended: 125; Radiation therapy type: External; Radiation total dose: 6600; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 33; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 922 days; disease-specific survival: no event (censored), 922 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 574 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LI-A67I-01A-31D-A306-01): tumor purity 0.77, ploidy 2.45, whole-genome doublings 1.
